Somatic mutation profile of tumor specimen C3L-00930-01 (aliquot CPT0027010009) from CPTAC case C3L-00930, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 72.7 years (26,559 days).
Specimen C3L-00930-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a594f2a-8053-4586-92c7-b46e281b63cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00930-71 (Blood Derived Normal), aliquot CPT0027070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11d1de21-8f8e-4fc4-855d-95c9896d1150

The open-access MAF lists 3,302 somatic variants for this specimen: 2,326 protein-altering or splice-affecting, 598 silent, 378 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,991, Silent 598, Nonsense Mutation 277, Intron 190, 3'UTR 64, RNA 55, 5'UTR 28, Splice Region 23, 3'Flank 21, Splice Site 20, 5'Flank 20, Frame Shift Ins 9.

Variants (750 of 3,302; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 95/213 reads (45%) | catalogued as rs118204093, CM074000, COSV53137319; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.6232C>T p.R2078* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as rs199422168, CM095684, COSV54125033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL3 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 76/164 reads (46%) | catalogued as rs1568359887, COSV52464695; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFP | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs132630259, CM950925, COSV55949739; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.*2776C>T | 3'UTR (SNP) | VAF 29/61 reads (48%) | catalogued as rs749421099, COSV57056397; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EDNRB | c.871C>T p.R291* (on ENST00000377211 / NM_001201397.1; = p.R201* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 65/79 reads (82%) | catalogued as rs104894391, CM020406; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 159/356 reads (45%) | catalogued as rs1559602356, COSV59534092, COSV59536060; ClinVar: pathogenic; called by muse, varscan2
- GJB2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371024165, CM002993, CM108184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNJ13 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as rs387906858, CM115615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LHCGR | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 287/311 reads (92%) | catalogued as rs121912524, CM960940, COSV54292419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs782396605, COSV68683552; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- OCRL | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 148/382 reads (39%) | catalogued as rs1556346316, CM990983, COSV63980169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 30/91 reads (33%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 33/77 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1679A>G p.D560G (on ENST00000521381 / NM_181523.3; = p.D290G on NM_181504.4) | Missense Mutation (SNP) | VAF 59/132 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57125813; called by muse, mutect2, varscan2
- POGZ | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 178/390 reads (46%) | catalogued as rs1557910873, COSV55034136; ClinVar: pathogenic; called by muse, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 55/112 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 188/413 reads (46%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 173/409 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SAMD9L | c.2956C>T p.R986C | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs1554341158, COSV59083574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.4786C>T p.R1596C (on ENST00000303395 / NM_001202435.3; = p.R1585C on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121917993, CM071991, COSV57683326; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 76/179 reads (42%) | catalogued as rs1480085793, CM093256; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.2423C>T p.T808I | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs1212676320, CM074575; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778604418, COSV59383298; called by muse, mutect2, varscan2
- AARD | c.35G>T p.R12I | Missense Mutation (SNP) | VAF 96/159 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as rs1392831257, COSV100991889; called by muse, mutect2, varscan2
- AARS1 | c.1139T>C p.V380A | Missense Mutation (SNP) | VAF 187/475 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs114327666; called by muse, mutect2, varscan2
- ABCA12 | c.4747A>C p.N1583H (on ENST00000272895 / NM_173076.3; = p.N1265H on NM_015657.3) | Missense Mutation (SNP) | VAF 100/239 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55954584; called by muse, mutect2, varscan2
- ABCA12 | c.1312G>A p.E438K (on ENST00000272895 / NM_173076.3; = p.E120K on NM_015657.3) | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs562998767, COSV55967677; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by muse, mutect2, varscan2
- ABCA12 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 128/350 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.061); catalogued as rs773100250, COSV55953508; called by muse, varscan2
- ABCA6 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs769159581; called by muse, mutect2, varscan2
- ABCB5 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); catalogued as COSV99329314; called by muse, mutect2, varscan2
- ABCB8 | c.1306G>T p.V436F (on ENST00000297504 / NM_001282291.2; = p.V419F on NM_007188.5) | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs371681720; called by muse, mutect2, varscan2
- ABCC12 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV60911397; called by muse, mutect2, varscan2
- ABCC2 | c.4250C>A p.S1417Y | Missense Mutation (SNP) | VAF 151/373 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs749883731; called by muse, mutect2, varscan2
- AC006059.2 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs747912716, COSV59607438; called by muse, mutect2, varscan2
- AC099489.1 | c.3667G>A p.E1223K | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs748719498, COSV104419884; called by muse, mutect2, varscan2
- ACOT12 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 45/119 reads (38%) | catalogued as rs776472585, COSV56897832; called by muse, mutect2, varscan2
- ACRBP | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs745904260; called by muse, mutect2, varscan2
- ACRBP | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs763689381; called by muse, mutect2, varscan2
- ACSL1 | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99860911; called by muse, mutect2, varscan2
- ADAM19 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 124/255 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57438574, COSV57441392; called by muse, mutect2, varscan2
- ADAM21 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 89/224 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as rs1259634123; called by muse, mutect2, varscan2
- ADAM23 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100008871; called by muse, mutect2, varscan2
- ADAMTS13 | c.3526C>T p.R1176W | Missense Mutation (SNP) | VAF 139/291 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs782300864; called by muse, mutect2, varscan2
- ADAMTS2 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs752742612; called by muse, mutect2, varscan2
- ADAMTS3 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as COSV54401790; called by muse, mutect2, varscan2
- ADAMTS5 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 150/314 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.835); catalogued as rs546124249, COSV53175804; called by muse, varscan2
- ADAMTS5 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286298815, COSV53175922; called by muse, mutect2, varscan2
- ADAP1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs1368212963; called by muse, mutect2, varscan2
- ADCY10 | c.4201G>A p.E1401K | Missense Mutation (SNP) | VAF 103/224 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs765104099; called by muse, mutect2, varscan2
- ADGRA2 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 88/263 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs138505796; called by muse, mutect2, varscan2
- ADGRE5 | c.2393G>A p.R798Q (on ENST00000242786 / NM_078481.4; = p.R705Q on NM_001784.5) | Missense Mutation (SNP) | VAF 105/197 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs747270370; called by muse, mutect2, varscan2
- ADGRF1 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs749959769; called by muse, mutect2, varscan2
- ADGRG4 | c.2790G>T p.M930I | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99794435; called by muse, mutect2, varscan2
- ADGRG7 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs748049635; called by muse, mutect2, varscan2
- ADGRV1 | c.17090C>T p.S5697F | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs745712471; called by muse, mutect2, varscan2
- ADNP2 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs766821105, COSV51537235; called by muse, mutect2, varscan2
- AFF4 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99535145; called by muse, mutect2, varscan2
- AFG3L2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 202/467 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs144035534; called by muse, mutect2, varscan2
- AGAP2 | c.1871G>A p.R624Q (on ENST00000547588 / NM_001122772.2; = p.R288Q on NM_014770.4) | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as rs984063768, COSV99222568; called by muse, mutect2, varscan2
- AGBL5 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983091121, COSV59936287, COSV59936860; called by muse, varscan2
- AGBL5 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 57/144 reads (40%) | catalogued as COSV59936550; called by muse, varscan2
- AGO2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99596045; called by muse, mutect2, varscan2
- AGO3 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 47/103 reads (46%) | catalogued as rs1244575080, COSV55790721, COSV55792811; called by muse, mutect2, varscan2
- AHCTF1 | c.1846C>T p.R616C (on ENST00000366508; = p.R590C on NM_015446.5) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs770031454, COSV58253892; called by muse, varscan2
- AHNAK | c.11237C>T p.S3746L | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs375616961; called by muse, mutect2, varscan2
- AIMP2 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs140208111, COSV99551988; called by muse, mutect2, varscan2
- AK9 | c.2080C>A p.L694I | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1253281655; called by muse, mutect2, varscan2
- AKAP6 | c.4522T>A p.S1508T | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.104); catalogued as COSV99800605; called by muse, mutect2
- AKAP9 | c.4672A>G p.T1558A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs746815931; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AL592490.1 | c.1960G>T p.G654C | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV69425287, COSV69426310; called by muse, mutect2, varscan2
- ALDH1L2 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs150637993, COSV51553589; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 89/205 reads (43%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALOX5 | c.1410C>A p.F470L | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV65554770; called by muse, mutect2, varscan2
- ALPK2 | c.6019G>T p.E2007* | Nonsense Mutation (SNP) | VAF 52/102 reads (51%) | catalogued as rs1482114339; called by muse, mutect2, varscan2
- ALS2CL | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs373261377; called by muse, mutect2, varscan2
- AMER1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1157288902, COSV57656246; called by muse, mutect2, varscan2
- AMER1 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV57664168; called by muse, mutect2, varscan2
- AMER3 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs369274817, COSV58466725; called by muse, mutect2, varscan2
- ANK1 | c.3013G>A p.E1005K | Missense Mutation (SNP) | VAF 199/546 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770510949; called by muse, mutect2, varscan2
- ANK2 | c.6205C>T p.R2069C | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs754572911, COSV52159875, COSV52189518; called by muse, mutect2, varscan2
- ANK2 | c.10401C>A p.F3467L | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV100003903; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 51/86 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1413777168, COSV99783895; called by muse, mutect2, varscan2
- ANKRD13A | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 137/325 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs781353037; called by muse, mutect2, varscan2
- ANKRD30A | c.1887A>C p.Q629H (on ENST00000611781; = p.Q573H on NM_052997.2) | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV64616714; called by muse, mutect2, varscan2
- ANKRD31 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1167129558, COSV57162438; called by muse, mutect2
- ANKRD31 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs924226501; called by muse, mutect2, varscan2
- ANKRD36 | c.3263G>T p.R1088I | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); catalogued as COSV70401705; called by muse, varscan2
- ANKRD36C | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); catalogued as rs772117678, COSV99754498; called by muse, mutect2, varscan2
- ANO1 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 93/226 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs768459625, COSV100303875; called by muse, mutect2, varscan2
- ANO6 | c.2048C>A p.S683Y | Missense Mutation (SNP) | VAF 132/318 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1304010599; called by muse, mutect2, varscan2
- ANOS1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 146/333 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1390812806; called by muse, mutect2, varscan2
- ANTKMT | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 92/213 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1388489446; called by muse, mutect2, varscan2
- ANTXR1 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 121/307 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.295); catalogued as COSV58012343; called by muse, mutect2, varscan2
- ANXA8 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 116/545 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1255805570; called by muse, mutect2, varscan2
- AOX1 | c.1422G>T p.K474N | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV65980312; called by muse, mutect2, varscan2
- APAF1 | c.3122G>A p.R1041Q (on ENST00000551964 / NM_181861.2; = p.R987Q on NM_001160.3) | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1284880203; called by muse, mutect2, varscan2
- APOBEC2 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs202202906, COSV99775372; called by muse, varscan2
- APPBP2 | c.1387C>A p.L463I | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99319460; called by muse, mutect2, varscan2
- AR | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65953973; called by muse, mutect2, varscan2
- ARAP2 | c.4037G>A p.R1346Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.838); catalogued as rs139889832; called by muse, mutect2, varscan2
- ARAP3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs536292464, COSV53349505; called by muse, mutect2, varscan2
- ARFGEF2 | c.3383G>A p.R1128Q | Missense Mutation (SNP) | VAF 134/319 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100903939; called by muse, mutect2, varscan2
- ARHGAP25 | c.1658C>A p.S553Y (on ENST00000409202 / NM_001007231.3; = p.S545Y on NM_014882.3) | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as rs201320026; called by muse, mutect2, varscan2
- ARHGAP28 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs761692539; called by muse, mutect2, varscan2
- ARHGAP32 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs761308907, COSV59848702; called by muse, mutect2, varscan2
- ARHGAP35 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1275300280; called by muse, mutect2, varscan2
- ARHGAP5 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 58/127 reads (46%) | catalogued as rs200628183; called by mutect2, varscan2
- ARHGEF12 | c.2827C>A p.L943M | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100755202; called by muse, mutect2, varscan2
- ARHGEF15 | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs534121147, COSV62724325, COSV62725188; called by muse, mutect2, varscan2
- ARHGEF16 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 105/220 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750316678; called by muse, mutect2, varscan2
- ARID1A | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 93/193 reads (48%) | catalogued as COSV100250607, COSV61371935; called by muse, mutect2, varscan2
- ARID5B | c.2606C>A p.S869Y | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.185); catalogued as rs201944744, COSV54415661; called by muse, mutect2, varscan2
- ARL6IP6 | c.203G>T p.R68I | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs1476219593; called by muse, mutect2, varscan2
- ARMC2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 50/125 reads (40%) | catalogued as COSV52900365; called by muse, mutect2, varscan2
- ARMC8 | c.1936G>A p.V646I (on ENST00000469044 / NM_001363941.2; = p.V632I on NM_015396.6) | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.796); catalogued as rs773224706; called by muse, mutect2, varscan2
- ARMC9 | c.2344G>A p.A782T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs1402115677; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.27); catalogued as COSV63438925; called by muse, mutect2, varscan2
- ARMH4 | c.2252G>T p.R751I | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775950494, COSV104388186, COSV50765093; called by muse, mutect2, varscan2
- ARPP21 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs748776109; called by muse, mutect2, varscan2
- ARX | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 193/470 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM133523, COSV66874794; called by muse, mutect2, varscan2
- ASCC3 | c.6409C>T p.R2137* | Nonsense Mutation (SNP) | VAF 59/140 reads (42%) | catalogued as rs760927168, COSV64973923, COSV64977816; called by muse, mutect2, varscan2
- ASPHD1 | c.1147G>A p.D383N | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1338614232; called by muse, mutect2, varscan2
- ASPHD2 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV53220800; called by muse, mutect2, varscan2
- ASPM | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766198125, COSV54132241; called by muse, mutect2, varscan2
- ASPM | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 79/187 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs776934561; called by muse, mutect2, varscan2
- ASTN2 | c.2156C>T p.T719M (on ENST00000313400 / NM_001365069.1; = p.T668M on NM_014010.5) | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.395); catalogued as rs775511096, COSV57776389; called by muse, mutect2, varscan2
- ASXL3 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 31/76 reads (41%) | catalogued as COSV52467737; called by muse, mutect2, varscan2
- ATF7IP | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as rs770191292, COSV53770969; called by muse, mutect2, varscan2
- ATG13 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs1436172888; called by muse, mutect2
- ATG2A | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as rs983657597; called by muse, mutect2, varscan2
- ATG9A | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60132703; called by muse, mutect2, varscan2
- ATP10D | c.3486T>G p.I1162M | Missense Mutation (SNP) | VAF 177/359 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.596); catalogued as rs767684890; called by muse, mutect2, varscan2
- ATP11C | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.747); catalogued as rs1045378104, COSV59564141; called by muse, mutect2, varscan2
- ATP12A | c.3105G>T p.K1035N | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV54512244; called by muse, mutect2, varscan2
- ATP13A4 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 138/293 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs748130648; called by muse, mutect2, varscan2
- ATP1A2 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 214/458 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs762330744, COSV63405023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B4 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs765757084, COSV100397940; called by muse, mutect2
- ATP6V0A4 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 111/251 reads (44%) | catalogued as COSV59475302; called by muse, mutect2, varscan2
- ATP6V0A4 | c.196+1G>A p.X66_splice | Splice Site (SNP) | VAF 39/140 reads (28%) | catalogued as rs1394471715; called by muse, mutect2, varscan2
- ATP6V1B1 | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 215/473 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as rs1553419387, COSV99313717; called by muse, mutect2, varscan2
- ATP6V1H | c.123G>T p.M41I | Missense Mutation (SNP) | VAF 88/149 reads (59%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV62216766; called by muse, mutect2, varscan2
- ATR | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63385289; called by muse, mutect2, varscan2
- ATRX | c.2519G>T p.R840I | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); catalogued as rs191682105, COSV64871123, COSV64876976; called by muse, mutect2
- ATRX | c.2304G>T p.K768N | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.327); catalogued as COSV64874006; called by muse, varscan2
- AVEN | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 86/205 reads (42%) | catalogued as rs766300982, COSV60734025; called by muse, varscan2
- AWAT1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as rs200977849, COSV65738641; called by muse, mutect2, varscan2
- B3GALNT1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 155/380 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs748945246, CD1314793, COSV100252091; called by muse, mutect2, varscan2
- BAIAP3 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.162); catalogued as rs757355425; called by muse, mutect2, varscan2
- BAZ1A | c.4438C>T p.R1480C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV62409067, COSV62409929; called by muse, mutect2, varscan2
- BAZ2B | c.2840T>A p.I947N | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1050062676; called by muse, mutect2, varscan2
- BBS9 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs899716022, COSV54157337; called by muse, mutect2, varscan2
- BCAR3 | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 76/166 reads (46%) | catalogued as COSV53074603; called by muse, mutect2, varscan2
- BCHE | c.1732T>G p.W578G | Missense Mutation (SNP) | VAF 80/142 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52257939; called by muse, varscan2
- BCHE | c.1698A>C p.E566D | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as rs1432076865; called by muse, varscan2
- BCHE | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100012650; called by muse, mutect2
- BEND6 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 55/133 reads (41%) | catalogued as rs1052954048, COSV66070514; called by muse, mutect2, varscan2
- BEST4 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.218); catalogued as COSV64733811; called by muse, mutect2, varscan2
- BIRC6 | c.14194C>T p.R4732* | Nonsense Mutation (SNP) | VAF 56/134 reads (42%) | catalogued as COSV70195462; called by muse, mutect2, varscan2
- BMI1 | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV64958895; called by muse, mutect2, varscan2
- BPGM | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs771037885, COSV61324703; called by muse, mutect2, varscan2
- BPIFA3 | c.598C>A p.L200I | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV64926054; called by muse, mutect2, varscan2
- BRINP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 141/297 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56297833; called by muse, mutect2, varscan2
- BRWD3 | c.2872C>T p.R958W | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1368496222, COSV64751478; called by muse, mutect2, varscan2
- BRWD3 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100955616; called by muse, mutect2, varscan2
- BTBD9 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757637334, COSV58431339; called by muse, mutect2, varscan2
- BUD23 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs141991727; called by muse, mutect2, varscan2
- C10orf67 | c.410C>A p.S137Y (on ENST00000323327; = p.S138Y on NM_153714.3) | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs372798012; called by muse, mutect2, varscan2
- C10orf88 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0.217); catalogued as rs570222008, COSV64403824; called by muse, mutect2, varscan2
- C10orf90 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 72/165 reads (44%) | catalogued as COSV52957513; called by muse, mutect2, varscan2
- C12orf29 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs772853450; called by muse, mutect2, varscan2
- C20orf96 | c.692G>A p.R231H (on ENST00000360321 / NM_153269.3; = p.R230H on NM_080571.1) | Missense Mutation (SNP) | VAF 77/179 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs766793783, COSV64404029; called by muse, mutect2, varscan2
- C2CD5 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1471759162, COSV61724558; called by muse, mutect2, varscan2
- C3AR1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 84/190 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs749041687, COSV50826025; called by muse, mutect2, varscan2
- C4orf54 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 87/181 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1353578745, COSV72766678; called by muse, mutect2, varscan2
- C6orf58 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs780579826, COSV100314770, COSV61667508; called by muse, mutect2, varscan2
- C7orf57 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 94/188 reads (50%) | catalogued as COSV62362409; called by muse, varscan2
- C7orf57 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs1028445620, COSV62362568; called by muse, varscan2
- C7orf57 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs768407235; called by muse, mutect2, varscan2
- C8orf34 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61375955; called by muse, mutect2, varscan2
- C9 | c.962A>G p.D321G | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs758705749; called by muse, mutect2
- CA8 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 385/624 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527113, COSV58773308; called by muse, mutect2, varscan2
- CACHD1 | c.3469G>A p.E1157K | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as rs1279703506, COSV51556006; called by muse, mutect2
- CACNA1A | c.4421A>G p.D1474G | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV64214146; called by muse, mutect2, varscan2
- CACNA1F | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59903562; called by muse, mutect2
- CACNB2 | c.427G>A p.E143K (on ENST00000324631 / NM_201596.3; = p.E88K on NM_000724.4) | Missense Mutation (SNP) | VAF 178/406 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as rs368719191; ClinVar: uncertain significance; called by muse, varscan2
- CADM1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 190/424 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs758008656, COSV59002787; called by muse, mutect2, varscan2
- CADPS | c.4057G>A p.D1353N | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs777645997, COSV51865517; called by muse, mutect2, varscan2
- CAMLG | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as rs751766092, COSV51804541; called by muse, mutect2, varscan2
- CAMSAP1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV56720766; called by muse, mutect2, varscan2
- CAPRIN2 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104377854; called by muse, mutect2
- CASP12 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs892949449, COSV65259603; called by muse, mutect2, varscan2
- CASP8AP2 | c.3352C>T p.R1118C | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767875273; called by muse, varscan2
- CAVIN4 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 118/241 reads (49%) | catalogued as COSV100293055; called by muse, mutect2, varscan2
- CBX1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs745952905; called by muse, mutect2, varscan2
- CCBE1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 288/625 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as rs147402390; called by muse, mutect2, varscan2
- CCDC178 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as rs150007249; called by muse, mutect2, varscan2
- CCDC180 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs367967921; called by muse, mutect2, varscan2
- CCDC39 | c.938C>A p.S313Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV56478458; called by muse, mutect2, varscan2
- CCDC39 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as rs1047910260, CM131301, COSV56478601; called by muse, mutect2, varscan2
- CCDC62 | c.1797G>T p.K599N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99457560; called by muse, mutect2, varscan2
- CCDC73 | c.2371G>T p.D791Y | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV58797891; called by muse, varscan2
- CCDC90B | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs148744063, COSV52623726; called by muse, mutect2, varscan2
- CCDC91 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as rs1565992969; called by muse, mutect2, varscan2
- CCNL1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99904246; called by muse, mutect2, varscan2
- CD163L1 | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 106/268 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769098820, COSV58019485; called by muse, mutect2, varscan2
- CD200R1L | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 123/317 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs1245378162, COSV68003867; called by muse, mutect2, varscan2
- CD22 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs143516468; called by muse, mutect2, varscan2
- CD244 | c.1069C>T p.R357* (on ENST00000368033 / NM_001166663.2; = p.R352* on NM_016382.4) | Nonsense Mutation (SNP) | VAF 94/213 reads (44%) | catalogued as rs138354575; called by muse, mutect2, varscan2
- CD40LG | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 141/345 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs1350282799, COSV65699086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD99L2 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs201144465, COSV60936211; called by muse, mutect2, varscan2
- CDAN1 | c.1267G>C p.V423L | Missense Mutation (SNP) | VAF 186/493 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1289189258; called by muse, mutect2, varscan2
- CDC42BPA | c.3736G>A p.E1246K (on ENST00000334218 / NM_001366019.2; = p.E1233K on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379223059, COSV62008453; called by muse, mutect2, varscan2
- CDC5L | c.814G>T p.E272* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as COSV101014876, COSV65177377; called by muse, mutect2, varscan2
- CDC7 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52310621; called by muse, varscan2
- CDH26 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.333); catalogued as rs760636765; called by muse, mutect2, varscan2
- CDH6 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 130/280 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV54065987, COSV54074286; called by muse, mutect2, varscan2
- CDH9 | c.2246C>T p.S749L | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1161575895, COSV50265477; called by muse, mutect2, varscan2
- CDK5RAP2 | c.127+1G>A p.X43_splice | Splice Site (SNP) | VAF 124/340 reads (36%) | catalogued as rs769323196; called by muse, mutect2, varscan2
- CDK7 | c.67-8C>A | Splice Region (SNP) | VAF 62/164 reads (38%) | catalogued as rs1231894200; called by muse, mutect2, varscan2
- CDK8 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.497); catalogued as COSV101037623; called by muse, varscan2
- CDNF | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV101012390; called by muse, mutect2, varscan2
- CDS2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1461927520; called by muse, mutect2, varscan2
- CENPF | c.4753G>A p.E1585K | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs777581291, COSV65276138, COSV65280179; called by muse, mutect2, varscan2
- CEP126 | c.2891G>T p.R964I | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs796755448, COSV104374678; called by muse, mutect2, varscan2
- CEP128 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1460947744, COSV55367965, COSV55388896; called by mutect2, varscan2
- CEP128 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs747268194, COSV53673976; called by muse, mutect2, varscan2
- CEP290 | c.2067G>T p.K689N | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as COSV100470277, COSV58351383; called by muse, mutect2, varscan2
- CEP83 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 48/107 reads (45%) | catalogued as COSV60407666, COSV60408122; called by muse, mutect2, varscan2
- CERKL | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV59213217; called by muse, mutect2, varscan2
- CES4A | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 114/245 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.26); catalogued as rs1447779082, COSV100110245; called by muse, mutect2, varscan2
- CFAP221 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.855); catalogued as rs368923748; called by muse, mutect2, varscan2
- CFAP45 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 167/417 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV63648087; called by muse, mutect2, varscan2
- CFAP47 | c.1893G>T p.K631N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs747060647, COSV52882246, COSV52887910; called by muse, mutect2, varscan2
- CFAP54 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as rs1300318364, COSV100127600; called by muse, mutect2, varscan2
- CFAP54 | c.6042G>T p.K2014N | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.699); catalogued as COSV61571319, COSV61571934; called by muse, mutect2, varscan2
- CFAP58 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 82/154 reads (53%) | catalogued as COSV57211987; called by muse, mutect2, varscan2
- CFAP61 | c.3605G>T p.R1202I | Missense Mutation (SNP) | VAF 31/392 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as COSV55622884; called by muse, mutect2
- CFTR | c.2499T>G p.F833L | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV50057235; called by muse, mutect2, varscan2
- CHAF1A | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748492659, COSV56671112; called by muse, mutect2, varscan2
- CHD4 | c.3974G>T p.R1325I (on ENST00000357008 / NM_001363606.2; = p.R1338I on NM_001273.5) | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58895972, COSV58909317; called by muse, mutect2, varscan2
- CHD4 | c.2884C>T p.R962C (on ENST00000357008 / NM_001363606.2; = p.R975C on NM_001273.5) | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58902074; called by muse, varscan2
- CHD7 | c.5764C>T p.R1922C | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1424250593; called by muse, mutect2, varscan2
- CHGB | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 114/259 reads (44%) | catalogued as COSV66761398; called by muse, mutect2, varscan2
- CHRM2 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57769632; called by muse, mutect2
- CHST15 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 114/246 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.521); catalogued as rs140903668; called by muse, mutect2, varscan2
- CHST7 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 145/344 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV99333011; called by muse, mutect2, varscan2
- CHSY3 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 78/174 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV59270876; called by muse, mutect2, varscan2
- CKAP2L | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs372791577; called by muse, mutect2, varscan2
- CLCA4 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.743); catalogued as rs369186095; called by muse, mutect2, varscan2
- CLCN5 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1373322324, COSV100259774; called by muse, mutect2, varscan2
- CLEC1A | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 139/324 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs753776952; called by muse, mutect2, varscan2
- CLEC2A | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs990945330, COSV60274212; called by muse, mutect2, varscan2
- CLEC5A | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 133/334 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782227023, COSV69397810; called by muse, mutect2, varscan2
- CLIP1 | c.2017G>A p.E673K (on ENST00000620786 / NM_001247997.1; = p.E662K on NM_002956.2) | Missense Mutation (SNP) | VAF 109/244 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs201352592; called by muse, mutect2, varscan2
- CLIP1 | c.1589G>A p.R530Q (on ENST00000620786 / NM_001247997.1; = p.R519Q on NM_002956.2) | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.115); catalogued as rs1324172594; called by muse, mutect2, varscan2
- CLRN2 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 189/466 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV71825264; called by muse, mutect2, varscan2
- CLTC | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 159/397 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52249469; called by muse, mutect2, varscan2
- CLTC | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747671478, COSV52244541; called by muse, mutect2, varscan2
- CMPK2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183755446, COSV56774351; called by muse, mutect2, varscan2
- CMTM5 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 101/221 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs751840348; called by muse, mutect2, varscan2
- CMTR2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 77/169 reads (46%) | catalogued as rs200221398, COSV57602756; called by muse, mutect2, varscan2
- CMYA5 | c.5134G>T p.E1712* | Nonsense Mutation (SNP) | VAF 71/146 reads (49%) | catalogued as COSV71404975; called by muse, mutect2, varscan2
- CMYA5 | c.9857T>G p.F3286C | Missense Mutation (SNP) | VAF 76/155 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV101484177; called by muse, mutect2, varscan2
- CNIH2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs1351510546, COSV61012184; called by muse, mutect2, varscan2
- CNOT11 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as rs141528136; called by muse, varscan2
- CNTN4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018920181, COSV61867465; called by muse, varscan2
- COIL | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 87/182 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as rs1201209890; called by muse, mutect2, varscan2
- COL12A1 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs775023310, COSV59391815; ClinVar: uncertain significance; called by muse, varscan2
- COL18A1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1217157250; called by muse, mutect2, varscan2
- COL19A1 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 86/202 reads (43%) | catalogued as rs759896577, COSV100506480, COSV59573575; called by muse, mutect2, varscan2
- COL20A1 | c.3022G>A p.V1008I | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs540834802, COSV58912703; called by muse, mutect2, varscan2
- COL3A1 | c.1282C>T p.R428* | Nonsense Mutation (SNP) | VAF 189/434 reads (44%) | catalogued as COSV58593877; called by muse, mutect2, varscan2
- COL3A1 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs770157568, COSV58592902; called by muse, mutect2, varscan2
- COL3A1 | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 104/266 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV58588975; called by muse, mutect2, varscan2
- COL4A5 | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 108/236 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1386149649, COSV60368691; called by muse, mutect2, varscan2
- COL6A5 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1259747495, COSV99593283; called by muse, mutect2, varscan2
- COLQ | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 143/329 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1422557889; called by muse, mutect2, varscan2
- COPG2 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs782309869, COSV58404153; called by muse, mutect2, varscan2
- COX15 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 188/435 reads (43%) | catalogued as COSV50012435; called by muse, mutect2, varscan2
- CPEB1 | c.833G>A p.G278E (on ENST00000617958; = p.G218E on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV55621869; called by muse, mutect2, varscan2
- CPOX | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 92/214 reads (43%) | catalogued as COSV51637819; called by muse, mutect2, varscan2
- CPS1 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 109/284 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs571936934, COSV51811408; called by muse, mutect2, varscan2
- CPSF6 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57012129; called by muse, mutect2, varscan2
- CPT1A | c.1687C>T p.R563C | Missense Mutation (SNP) | VAF 156/344 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs747315058; called by muse, mutect2, varscan2
- CPXM2 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs764574900; called by muse, mutect2, varscan2
- CRB1 | c.1978T>C p.S660P | Missense Mutation (SNP) | VAF 163/390 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV100957892; called by muse, mutect2, varscan2
- CREB1 | c.382C>A p.L128I (on ENST00000432329 / NM_134442.5; = p.L114I on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100783628; called by muse, mutect2, varscan2
- CREBBP | c.3840C>A p.F1280L | Missense Mutation (SNP) | VAF 232/483 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.931); catalogued as COSV52124537; called by muse, mutect2, varscan2
- CRIM1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 75/157 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.846); catalogued as rs774406061, COSV54859095; called by muse, mutect2, varscan2
- CRYBG3 | c.5969C>A p.S1990Y | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51709616; called by muse, mutect2, varscan2
- CSMD1 | c.5791C>T p.R1931W (on ENST00000520002; = p.R1930W on NM_033225.6) | Missense Mutation (SNP) | VAF 70/321 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1257992819, COSV59378890; called by muse, mutect2, varscan2
- CSMD3 | c.10052C>T p.S3351F (on ENST00000297405 / NM_001363185.1; = p.S3182F on NM_052900.3) | Missense Mutation (SNP) | VAF 175/570 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs1310279550, COSV52137625, COSV99838503; called by muse, mutect2, varscan2
- CSNK1G2 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1311974157; called by muse, mutect2
- CSPP1 | c.1256G>A p.R419Q (on ENST00000676605; = p.R378Q on NM_024790.6) | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.083); catalogued as rs925945579; called by muse, mutect2, varscan2
- CSTF2T | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 176/408 reads (43%) | catalogued as rs760010167, COSV58656568; called by muse, mutect2, varscan2
- CSTL1 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs140584733; called by muse, mutect2, varscan2
- CTSW | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 12/233 reads (5%) | catalogued as COSV57171669; called by muse, mutect2
- CTTNBP2 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs771192411, COSV99353638; called by muse, mutect2, varscan2
- CUL4B | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100341059; called by muse, mutect2
- CUZD1 | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs772196100; called by muse, varscan2
- CWC22 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748093590, COSV55427056; called by muse, mutect2, varscan2
- CYP20A1 | c.904T>G p.L302V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as COSV100619152; called by muse, mutect2, varscan2
- CYP4F22 | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 152/337 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as rs757078629, COSV54107300; called by muse, mutect2, varscan2
- DAAM1 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs767797655, COSV62834416; called by muse, mutect2
- DAB1 | c.1214T>G p.V405G (on ENST00000371231; = p.V372G on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100976336; called by muse, mutect2, varscan2
- DAPL1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs745794395, COSV59353180; called by muse, varscan2
- DBF4B | c.761C>A p.S254Y | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as rs774436262, COSV59258932, COSV59261867; called by muse, mutect2, varscan2
- DCAF4 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 101/260 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs771941250, COSV62319294; called by muse, mutect2, varscan2
- DCAF6 | c.2184C>A p.F728L (on ENST00000312263 / NM_001349778.1; = p.F748L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56576008; called by muse, mutect2, varscan2
- DCLRE1B | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as rs138603501; called by muse, mutect2, varscan2
- DCX | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 119/314 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs892512121, COSV57566410; called by muse, mutect2, varscan2
- DDX24 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 64/344 reads (19%) | catalogued as rs1489002184; called by muse, mutect2, varscan2
- DEFA6 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 109/166 reads (66%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs775931969; called by muse, varscan2
- DENND2B | c.1895G>T p.R632I | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100567806; called by muse, mutect2, varscan2
- DENND3 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs1001301736, COSV52802817; called by muse, mutect2, varscan2
- DENND4A | c.2896C>T p.R966C | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777360009; called by muse, mutect2, varscan2
- DENND4A | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 84/233 reads (36%) | catalogued as rs780450925, COSV71265577; called by muse, mutect2, varscan2
- DHX9 | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1047562905, COSV100841496; called by muse, mutect2, varscan2
- DIPK2A | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 157/341 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1367040240, COSV59856423; called by muse, mutect2, varscan2
- DISP3 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53825543; called by muse, mutect2, varscan2
- DKK1 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV64760696; called by muse, mutect2
- DKK2 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 202/452 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761402051, COSV53394372; called by muse, mutect2, varscan2
- DLEC1 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762324276; called by muse, mutect2, varscan2
- DLG2 | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65864795; called by muse, mutect2, varscan2
- DLGAP1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1298741540, COSV59800368; called by muse, mutect2, varscan2
- DLL4 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs986124396, COSV99989706; called by muse, mutect2
- DMKN | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 142/363 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs746914699, COSV60084177; called by muse, mutect2, varscan2
- DMPK | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as rs370041130; called by muse, mutect2, varscan2
- DNAH11 | c.4891G>A p.V1631I | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs766901693, COSV60963386; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH12 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 91/194 reads (47%) | catalogued as COSV61061954; called by muse, mutect2, varscan2
- DNAH14 | c.4519C>T p.R1507* (on ENST00000445597; = p.R1912* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as rs930272445, COSV60737076; called by muse, mutect2, varscan2
- DNAH14 | c.9095T>G p.F3032C (on ENST00000445597; = p.F3796C on NM_001367479.1) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100587467; called by muse, mutect2, varscan2
- DNAH17 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs563972044; called by muse, mutect2, varscan2
- DNAH2 | c.5812G>T p.E1938* | Nonsense Mutation (SNP) | VAF 128/305 reads (42%) | catalogued as COSV66718205; called by muse, mutect2, varscan2
- DNAH3 | c.8360C>T p.S2787L | Missense Mutation (SNP) | VAF 212/483 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs773491356, COSV54544723; called by muse, mutect2, varscan2
- DNAH3 | c.1190A>G p.H397R | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762020805; called by muse, mutect2, varscan2
- DNAH5 | c.12454G>A p.D4152N | Missense Mutation (SNP) | VAF 219/515 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs761422282, COSV54226224, COSV54257014; called by muse, mutect2, varscan2
- DNAH5 | c.11118G>T p.E3706D | Missense Mutation (SNP) | VAF 126/256 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444522; called by muse, mutect2, varscan2
- DNAH5 | c.9919G>A p.A3307T | Missense Mutation (SNP) | VAF 139/384 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs757212818, COSV54221930; called by muse, mutect2, varscan2
- DNAH5 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 172/400 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs757056449, CM150542, COSV54237241; called by muse, mutect2, varscan2
- DNAH5 | c.1176G>T p.K392N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54251612, COSV99447704; called by muse, mutect2, varscan2
- DNAH7 | c.4658C>T p.S1553L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs769152463, COSV56763783; called by muse, mutect2
- DNAH7 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 36/88 reads (41%) | catalogued as COSV100415037, COSV56760037; called by mutect2, varscan2
- DNAH9 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 105/214 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780569703; called by muse, mutect2, varscan2
- DNAH9 | c.12742C>T p.R4248C | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52344058; called by muse, mutect2, varscan2
- DNAJB11 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as rs773690271, COSV54002563; called by muse, mutect2, varscan2
- DNM3 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs748395660, COSV62463290; called by muse, mutect2, varscan2
- DOCK3 | c.2765C>T p.S922L | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1273717275, COSV56533165; called by muse, mutect2, varscan2
- DOCK4 | c.5558C>T p.S1853F | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.809); catalogued as COSV70236539; called by muse, mutect2
- DOCK4 | c.3682G>A p.E1228K | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as rs771879680, COSV69854261; called by muse, mutect2, varscan2
- DOCK4 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs768165193, COSV101455551; called by muse, mutect2, varscan2
- DOCK7 | c.3028T>C p.F1010L (on ENST00000635253 / NM_001367561.1; = p.F979L on NM_033407.3) | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs1438191021; called by muse, mutect2, varscan2
- DPP10 | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs370150768; called by muse, mutect2, varscan2
- DPP6 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); catalogued as rs1263209878; called by muse, mutect2, varscan2
- DPP8 | c.2470C>T p.R824C (on ENST00000341861 / NM_001320875.2; = p.R708C on NM_017743.6) | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55679883; called by muse, mutect2, varscan2
- DROSHA | c.1243T>C p.C415R | Missense Mutation (SNP) | VAF 123/243 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV60783754; called by muse, mutect2, varscan2
- DRP2 | c.2638G>A p.E880K | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs765750077, COSV67871426; called by muse, mutect2, varscan2
- DSC3 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV64574089; called by muse, mutect2, varscan2
- DSCC1 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs367780001; called by muse, mutect2, varscan2
- DSEL | c.2621G>A p.G874E | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765985113, COSV59493358; called by muse, mutect2, varscan2
- DSP | c.2747A>C p.K916T | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs1554107730, COSV101131199; ClinVar: uncertain significance; called by muse, mutect2
- DSTYK | c.831C>A p.F277L | Missense Mutation (SNP) | VAF 119/280 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs567432027, COSV100904514; called by muse, mutect2, varscan2
- DTWD1 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1037465844, COSV52071402; called by muse, mutect2, varscan2
- DYNC1H1 | c.3107C>T p.S1036L | Missense Mutation (SNP) | VAF 190/380 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs369033191; ClinVar: uncertain significance; called by mutect2, varscan2
- DYNC2I1 | c.1925G>A p.R642Q | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs1382551742, COSV68105989; called by muse, mutect2, varscan2
- DYSF | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 162/357 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs121908960, CM078431; called by muse, mutect2, varscan2
- DZIP1 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 46/47 reads (98%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs765762974, COSV61269773; called by muse, mutect2, varscan2
- ECD | c.1423G>T p.E475* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV65900333; called by muse, mutect2, varscan2
- EEF2 | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100500684, COSV58580415; called by muse, mutect2, varscan2
- EFCAB2 | c.623G>A p.R208Q (on ENST00000366522; = p.R72Q on NM_032328.3) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.642); catalogued as rs773087834, COSV63657165; called by muse, mutect2, varscan2
- EFCAB3 | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs773660770, COSV59503552; called by muse, mutect2, varscan2
- EFHC1 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 157/345 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs928430333, COSV64135895; called by muse, mutect2, varscan2
- EIF2S1 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56452113; called by muse, mutect2, varscan2
- EIF3G | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1187915764; called by muse, mutect2, varscan2
- EMB | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 47/119 reads (39%) | catalogued as rs568724287, COSV57483356; called by muse, mutect2, varscan2
- EMILIN2 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.059); catalogued as COSV54428703; called by muse, mutect2, varscan2
- EML4 | c.1480G>T p.G494* | Nonsense Mutation (SNP) | VAF 13/125 reads (10%) | catalogued as COSV100580890; called by muse, mutect2
- EMP3 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 102/231 reads (44%) | catalogued as rs763027671, COSV53155187; called by muse, mutect2, varscan2
- ENO3 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs772218199, CM149900; called by muse, mutect2, varscan2
- ENOX2 | c.1108C>T p.R370C (on ENST00000338144 / NM_001382520.1; = p.R341C on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199818795, COSV57650385; called by muse, mutect2, varscan2
- ENOX2 | c.343C>T p.L115F (on ENST00000338144 / NM_001382520.1; = p.L86F on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100584542, COSV57657933; called by muse, varscan2
- EP400 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 127/307 reads (41%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.654); catalogued as rs766432250, COSV57780225; called by muse, mutect2, varscan2
- EPHA6 | c.2176C>T p.R726C (on ENST00000389672 / NM_001080448.3; = p.R118C on NM_173655.4) | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs774266264, COSV67565553; called by muse, mutect2, varscan2
- EPRS1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as rs200738924, COSV65101513; called by muse, mutect2, varscan2
- EPYC | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV53799098; called by muse, mutect2, varscan2
- ERC1 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 91/189 reads (48%) | catalogued as rs377704599, COSV61691326; called by muse, mutect2, varscan2
- ERCC6L2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 21/48 reads (44%) | catalogued as rs1337089169; called by muse, mutect2, varscan2
- ERO1A | c.1162A>C p.I388L | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV67471809; called by muse, mutect2, varscan2
- ERVV-2 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs1254659726; called by mutect2, varscan2
- ERVW-1 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs139139983; called by muse, mutect2, varscan2
- ESCO1 | c.1421A>C p.K474T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV52519083; called by muse, mutect2, varscan2
- ESPNL | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 115/258 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.102); catalogued as rs142459355; called by muse, mutect2
- ESYT3 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 148/348 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as rs769328420, COSV56679687; called by muse, mutect2, varscan2
- EVC2 | c.3751G>A p.E1251K | Missense Mutation (SNP) | VAF 127/239 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as rs769520928; called by muse, mutect2, varscan2
- EVPL | c.4073G>A p.R1358H | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs777686326, COSV56910219; called by muse, mutect2, varscan2
- EXOC4 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 108/269 reads (40%) | catalogued as rs1446395002, COSV54090129; called by muse, mutect2, varscan2
- EXOC6 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs752026979, COSV65316106; called by muse, mutect2, varscan2
- EYA4 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 120/245 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as rs755455584, COSV62046101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F5 | c.6257C>T p.S2086L | Missense Mutation (SNP) | VAF 133/333 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1385521861, CM107144, COSV63123118; called by muse, mutect2, varscan2
- FAM135B | c.3932T>C p.V1311A | Missense Mutation (SNP) | VAF 189/309 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99420601; called by muse, mutect2, varscan2
- FAM149A | c.922G>A p.E308K (on ENST00000356371 / NM_001367768.2; = p.E17K on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1034317509, COSV57025625; called by muse, mutect2, varscan2
- FAM151B | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.197); catalogued as COSV56471777, COSV56475216; called by muse, mutect2, varscan2
- FAM161B | c.1775C>T p.A592V (on ENST00000651776; = p.A529V on NM_152445.3) | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs150485088; called by muse, mutect2, varscan2
- FAM184B | c.2839C>T p.R947W | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1392152441; called by muse, mutect2, varscan2
- FAM186A | c.6656G>A p.R2219Q | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs1411428395; called by muse, mutect2, varscan2
- FAM186A | c.3496A>G p.K1166E | Missense Mutation (SNP) | VAF 107/170 reads (63%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1488190251, COSV59247583; called by mutect2, varscan2
- FAM47A | c.2004C>A p.F668L | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV60494352; called by muse, mutect2, varscan2
- FAM47A | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV60496448; called by muse, mutect2, varscan2
- FAM50A | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.947); catalogued as rs370055697; called by muse, mutect2, varscan2
- FAM91A1 | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 52/150 reads (35%) | catalogued as rs759145296, COSV58238607; called by muse, varscan2
- FANCD2 | c.3031G>T p.E1011* | Nonsense Mutation (SNP) | VAF 115/309 reads (37%) | catalogued as COSV55033901, COSV55046411; called by muse, mutect2, varscan2
- FANCM | c.5792G>A p.R1931Q | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs773595869, COSV57500404; called by muse, mutect2, varscan2
- FARSB | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99918386; called by muse, mutect2, varscan2
- FARSB | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs548159804; called by muse, varscan2
- FARSB | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs774121599, COSV56051268; called by muse, varscan2
- FAT1 | c.5566C>T p.R1856C | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs576312211; called by muse, mutect2, varscan2
- FAT3 | c.11566G>T p.E3856* | Nonsense Mutation (SNP) | VAF 30/118 reads (25%) | catalogued as COSV99966811, COSV99969470; called by muse, mutect2, varscan2
- FBLL1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs751310063; called by muse, mutect2, varscan2
- FBN1 | c.8386G>A p.E2796K | Missense Mutation (SNP) | VAF 120/268 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.04); catalogued as rs112310699, COSV57321466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBP2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs550526190, COSV64695235; called by muse, mutect2, varscan2
- FBXL19 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs780158953; called by muse, mutect2, varscan2
- FBXO22 | c.608G>T p.R203I | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV57616554; called by muse, mutect2, varscan2
- FBXO33 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.925); catalogued as rs745469608; called by muse, mutect2, varscan2
- FBXO38 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs896205714, COSV57028108; called by muse, mutect2, varscan2
- FBXO39 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 131/288 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs373411596; called by muse, mutect2, varscan2
- FBXO39 | c.1205G>A p.R402K | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV58621427; called by muse, mutect2, varscan2
- FER1L5 | c.2807G>A p.R936H (on ENST00000623019; = p.R943H on NM_001293083.2) | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1004716219; called by muse, mutect2, varscan2
- FER1L6 | c.5345C>T p.P1782L | Missense Mutation (SNP) | VAF 59/252 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67552859; called by muse, mutect2, varscan2
- FGA | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs746940107, COSV57401601; called by muse, mutect2, varscan2
- FGG | c.123C>T p.F41= | Splice Region (SNP) | VAF 63/148 reads (43%) | catalogued as rs141554929; called by muse, mutect2, varscan2
- FLG | c.5693C>T p.S1898L | Missense Mutation (SNP) | VAF 223/563 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs758337721, COSV64238844; called by muse, mutect2, varscan2
- FLG2 | c.1511G>A p.G504D | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV66174570; called by muse, mutect2, varscan2
- FLI1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs369164251; called by muse, mutect2, varscan2
- FLNA | c.6772G>A p.E2258K (on ENST00000369850 / NM_001110556.2; = p.E2250K on NM_001456.3) | Missense Mutation (SNP) | VAF 203/440 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV100774175; called by muse, mutect2, varscan2
- FLRT2 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1342192331; called by muse, mutect2, varscan2
- FMN1 | c.2364C>A p.C788* (on ENST00000616417 / NM_001277313.2; = p.C565* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 134/306 reads (44%) | catalogued as COSV100568753; called by muse, mutect2, varscan2
- FMR1 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54424578; called by muse, mutect2, varscan2
- FMR1 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54426155; called by muse, mutect2, varscan2
- FN1 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 144/377 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778879562, COSV100118539; called by muse, mutect2, varscan2
- FNBP1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs778471637, COSV63086861; called by muse, mutect2, varscan2
- FNIP1 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as COSV57194262; called by muse, mutect2, varscan2
- FOXK1 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 99/227 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs1162001404; called by muse, mutect2, varscan2
- FREM1 | c.2159C>A p.S720* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as rs1172241569; called by muse, mutect2, varscan2
- FRMPD1 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 56/123 reads (46%) | catalogued as rs979040535, COSV100899520, COSV100899551; called by muse, mutect2, varscan2
- FRMPD3 | c.3292C>A p.L1098I | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV52195752; called by muse, mutect2, varscan2
- FRMPD4 | c.1200C>A p.L400= | Splice Region (SNP) | VAF 51/111 reads (46%) | catalogued as COSV101044057; called by muse, mutect2, varscan2
- FTCDNL1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1432599935; called by muse, mutect2, varscan2
- FTHL17 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 103/227 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV63267710; called by muse, mutect2, varscan2
- FTO | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 214/458 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs558995583, COSV99193237; called by muse, mutect2, varscan2
- FUZ | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 247/621 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs749706858, COSV58241742; called by muse, mutect2, varscan2
- FXR1 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59761970, COSV59762263; called by muse, mutect2, varscan2
- GABBR2 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99409789; called by muse, mutect2, varscan2
- GABPA | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61395301; called by muse, mutect2, varscan2
- GABRA1 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.453); catalogued as rs778103654, COSV50109805; called by muse, mutect2, varscan2
- GABRA2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62919553; called by muse, varscan2
- GABRG2 | c.1139C>T p.S380F (on ENST00000361925 / NM_001375343.1; = p.S340F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/428 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729386, COSV62718810; called by muse, varscan2
- GALNT15 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs139235672, COSV100327373; called by muse, mutect2, varscan2
- GALNTL6 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1011629190, COSV72491025, COSV72493992; called by muse, mutect2, varscan2
- GAPDHS | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 90/169 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs757066531, COSV55882178; called by muse, mutect2, varscan2
- GAPDHS | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 28/188 reads (15%) | catalogued as COSV55881287; called by muse, mutect2, varscan2
- GARRE1 | c.1872G>T p.E624D | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as COSV55105655; called by muse, mutect2, varscan2
- GBP4 | c.1209G>T p.E403D | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV63255132; called by muse, mutect2, varscan2
- GBP5 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 88/220 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as rs141794180, COSV100599990; called by muse, mutect2, varscan2
- GCN1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs780399060; called by muse, mutect2, varscan2
- GCNA | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 57/148 reads (39%) | catalogued as COSV101032518; called by muse, mutect2, varscan2
- GCNT2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 210/478 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77950633; called by muse, mutect2, varscan2
- GCNT2 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 110/286 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs766682666; called by muse, mutect2, varscan2
- GDA | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52994899; called by muse, mutect2, varscan2
- GDF10 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs1040533972; called by muse, mutect2, varscan2
- GFRAL | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV61231407, COSV61232771; called by muse, varscan2
- GIMAP1 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV100211869; called by muse, mutect2, varscan2
- GIMAP6 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 91/220 reads (41%) | catalogued as COSV100188315, COSV61032894; called by muse, mutect2, varscan2
- GJB6 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 117/242 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1231348800, COSV53831748; called by muse, mutect2, varscan2
- GJD2 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 85/174 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51749008; called by muse, mutect2, varscan2
- GLUD1 | c.964C>A p.R322S | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as CM004847; called by muse, mutect2, varscan2
- GLUD2 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 165/427 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60151615; called by muse, mutect2, varscan2
- GNB5 | c.569C>T p.S190F (on ENST00000261837 / NM_016194.4; = p.S148F on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV55898705, COSV55901688; called by muse, mutect2, varscan2
- GNE | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs759799606; called by muse, mutect2
- GNL2 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 162/370 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs760375299; called by muse, mutect2, varscan2
- GNL2 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs769099338, COSV66081115; called by muse, mutect2, varscan2
- GNPTAB | c.3566G>A p.R1189Q | Missense Mutation (SNP) | VAF 118/305 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs141007019; called by muse, mutect2, varscan2
- GNPTAB | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs779572693, CM163753, COSV54776658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs755532884, COSV71181152; called by mutect2, varscan2
- GOLGA8A | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); catalogued as rs765832278; called by mutect2, varscan2
- GOLGA8H | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs776844064; called by muse, mutect2, varscan2
- GOLM1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs372897298; called by muse, mutect2, varscan2
- GOLPH3L | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1250943199; called by muse, mutect2, varscan2
- GOT1L1 | c.901C>A p.L301I | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756980233; called by muse, mutect2, varscan2
- GP2 | c.1525G>A p.G509S (on ENST00000381362 / NM_001007240.3; = p.G506S on NM_001502.4) | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs548202424, COSV100221587; called by muse, varscan2
- GPA33 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100900950; called by muse, mutect2, varscan2
- GPATCH2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs772330754; called by muse, mutect2, varscan2
- GPR139 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58502777; called by muse, mutect2, varscan2
- GPR149 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 99/213 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67665860; called by muse, mutect2, varscan2
- GPR155 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.223); catalogued as rs140641354; called by muse, mutect2, varscan2
- GPR174 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.241); catalogued as rs906234328, COSV52133303, COSV52133417; called by muse, mutect2, varscan2
- GPR55 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 76/161 reads (47%) | catalogued as COSV99060293; called by muse, mutect2, varscan2
- GPR63 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 97/235 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.178); catalogued as COSV57739374; called by muse, mutect2, varscan2
- GRAMD4 | c.1383G>A p.A461= | Splice Region (SNP) | VAF 36/83 reads (43%) | catalogued as rs147965854; called by muse, mutect2, varscan2
- GRID1 | c.2690C>T p.S897L | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs779461467, COSV60055756; called by muse, mutect2, varscan2
- GRID1 | c.1436G>A p.G479D | Missense Mutation (SNP) | VAF 118/308 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1363163817; called by muse, mutect2, varscan2
- GRID2IP | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1176405986; called by muse, mutect2, varscan2
- GRIK5 | c.1969G>T p.D657Y | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99489844; called by muse, mutect2
- GRIN2B | c.3160G>A p.D1054N | Missense Mutation (SNP) | VAF 173/413 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.825); catalogued as COSV74206640; called by muse, mutect2, varscan2
- GRIN3A | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 129/291 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs941485044, COSV62450158; called by muse, mutect2, varscan2
- GRM7 | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 156/341 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387453915, COSV100735701; called by muse, mutect2, varscan2
- GRWD1 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 175/384 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs766021879; called by muse, mutect2, varscan2
- GSAP | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766464521; called by muse, mutect2, varscan2
- GSDMC | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 82/316 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs375510820; called by muse, mutect2, varscan2
- GTF2F1 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 104/286 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as rs748571217, COSV66726980; called by muse, varscan2
- GUSB | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 210/445 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200149500; called by muse, mutect2, varscan2
- GVQW3 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 80/165 reads (48%) | catalogued as rs756869819; called by muse, mutect2, varscan2
- GYS2 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 95/244 reads (39%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as rs751135925, COSV53921084; called by muse, mutect2, varscan2
- H4C13 | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs1369995595, COSV60694758; called by muse, mutect2, varscan2
- HAUS6 | c.1295A>G p.D432G | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs750017534; called by muse, mutect2, varscan2
- HCN4 | c.2356G>A p.A786T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771516987; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCN4 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 171/361 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56082467; called by muse, mutect2, varscan2
- HDAC4 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 156/376 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.732); catalogued as rs766581830, COSV61871658; called by muse, mutect2, varscan2
- HEATR5A | c.2809A>C p.N937H | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs368505431; called by muse, mutect2, varscan2
- HECTD4 | c.3802G>T p.E1268* | Nonsense Mutation (SNP) | VAF 21/470 reads (4%) | catalogued as COSV61177731; called by muse, mutect2
- HECW2 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 100/233 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs143599492; called by muse, mutect2, varscan2
- HEPH | c.577C>T p.R193* (on ENST00000343002; = p.R247* on NM_138737.5) | Nonsense Mutation (SNP) | VAF 58/149 reads (39%) | catalogued as rs1178422613, COSV57963210; called by muse, mutect2, varscan2
- HEPHL1 | c.1000G>T p.E334* | Nonsense Mutation (SNP) | VAF 108/255 reads (42%) | catalogued as COSV59896091; called by muse, mutect2, varscan2
- HERC2 | c.7361C>T p.S2454L | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs879255382, COSV55350151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HERC2 | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1193330360, COSV55318403; called by muse, mutect2, varscan2
- HERC5 | c.1342G>T p.A448S | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99987913; called by muse, mutect2, varscan2
- HERC6 | c.200-1G>T p.X67_splice | Splice Site (SNP) | VAF 56/148 reads (38%) | catalogued as rs770065117, COSV52028332; called by muse, mutect2, varscan2
- HFM1 | c.3185C>T p.A1062V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as rs1051937552; called by muse, mutect2, varscan2
- HHIP | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs746714216, COSV56836455; called by muse, mutect2, varscan2
- HHLA1 | c.547G>T p.E183* | Nonsense Mutation (SNP) | VAF 121/196 reads (62%) | catalogued as COSV51849726; called by muse, mutect2, varscan2
- HIGD2B | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 169/378 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.141); catalogued as rs774583212, COSV61231606; called by muse, mutect2, varscan2
- HIPK2 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 147/354 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61231379; called by muse, mutect2, varscan2
- HNRNPAB | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as COSV57425821; called by muse, varscan2
- HNRNPUL1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs199709764, COSV54563375; called by muse, mutect2, varscan2
- HOOK1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs368144967; called by muse, mutect2, varscan2
- HOOK1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs758877382; called by muse, mutect2, varscan2
- HPX | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 129/316 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs764038271, COSV56419559; called by muse, mutect2, varscan2
- HR | c.3345G>T p.E1115D | Missense Mutation (SNP) | VAF 27/549 reads (5%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.707); catalogued as COSV57195085; called by muse, mutect2
- HRH2 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 14/229 reads (6%) | catalogued as COSV51573735; called by muse, mutect2
- HSD17B4 | c.205G>A p.D69N (on ENST00000414835 / NM_001199291.3; = p.D44N on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as CD060117; called by muse, mutect2, varscan2
- HSD17B4 | c.1412A>G p.Y471C (on ENST00000414835 / NM_001199291.3; = p.Y446C on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.676); catalogued as rs768553274; called by muse, mutect2, varscan2
- HSPA12B | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs373904414; called by muse, mutect2, varscan2
- HTR2B | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 87/420 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.078); catalogued as rs781269061, COSV51449246; called by muse, varscan2
- HTR5A | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs753684277, COSV55282760, COSV55286022; called by muse, mutect2, varscan2
- HUWE1 | c.147C>T p.C49= | Splice Region (SNP) | VAF 118/289 reads (41%) | catalogued as rs149435515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HYDIN | c.10441C>T p.R3481W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs76078590, COSV101154480; called by mutect2, varscan2
- ICA1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as rs768609861, COSV55584736; called by muse, mutect2
- IDO2 | c.95C>A p.S32Y (on ENST00000389060; = p.S45Y on NM_194294.2) | Missense Mutation (SNP) | VAF 123/188 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as rs769653508, COSV58425221, COSV58429877; called by muse, mutect2, varscan2
- IFNA8 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 207/462 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0.042); catalogued as rs201661816, COSV66504563; called by muse, mutect2, varscan2
- IFT172 | c.4223C>T p.S1408L | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.114); catalogued as rs940572325, COSV99561897; called by muse, mutect2, varscan2
- IFT43 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 170/418 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995075025, COSV53138392; called by muse, varscan2
- IGBP1P2 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as rs754051211; called by muse, mutect2, varscan2
- IGF2R | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100806628; called by muse, mutect2, varscan2
- IGHV3-30 | c.223A>C p.S75R | Missense Mutation (SNP) | VAF 88/1538 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs759046734; called by muse, mutect2
- IGHV3-72 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 99/235 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.089); catalogued as COSV101455368, COSV70409497; called by muse, mutect2, varscan2
- IGLV5-48 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs774578844; called by muse, varscan2
- IGSF1 | c.269C>A p.S90* | Nonsense Mutation (SNP) | VAF 24/286 reads (8%) | catalogued as COSV63837621; called by muse, mutect2
- IGSF10 | c.7586G>A p.R2529Q | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs146905174, COSV56368510; called by muse, mutect2, varscan2
- IL10RA | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV57142084; called by muse, mutect2, varscan2
- IL16 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs750324638, COSV100266872; called by muse, mutect2, varscan2
- IL1RAPL1 | c.-24G>T | Splice Region (SNP) | VAF 75/201 reads (37%) | catalogued as COSV100149311; called by muse, mutect2, varscan2
- IL1RAPL1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199864130, COSV56250433; called by muse, mutect2, varscan2
- IL2RG | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs774953764, COSV52149447; called by muse, mutect2, varscan2
- IL31RA | c.513G>T p.M171I | Missense Mutation (SNP) | VAF 125/302 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs146018754; called by muse, mutect2, varscan2
- INPP4B | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | catalogued as rs1332432216, COSV99523543; called by muse, mutect2, varscan2
- INPP5A | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs374027590; called by muse, mutect2, varscan2
- INPP5D | c.1654C>T p.R552* (on ENST00000445964 / NM_001017915.3; = p.R551* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 54/115 reads (47%) | catalogued as COSV64038649; called by muse, mutect2, varscan2
- INPPL1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 113/209 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV53357592; called by muse, mutect2, varscan2
- IRF7 | c.1516G>A p.E506K (on ENST00000397566; = p.E493K on NM_001572.5) | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs750066562, COSV52755944; called by muse, mutect2, varscan2
- IRS1 | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs747700323, COSV59338127; called by muse, mutect2, varscan2
- ISG20L2 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV57461241; called by muse, mutect2, varscan2
- ITGA2B | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 125/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1280021793; called by muse, mutect2, varscan2
- ITGAL | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV63320131; called by muse, mutect2, varscan2
- ITGAM | c.741G>T p.K247N | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54936482; called by muse, mutect2, varscan2
- ITIH2 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs377214728; called by muse, mutect2, varscan2
- ITM2A | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 92/194 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100964456; called by muse, varscan2
- ITPRID1 | c.52A>C p.K18Q | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as rs1436301130; called by muse, mutect2, varscan2
- JAG2 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 250/530 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs1490700973; called by muse, mutect2, varscan2
- JAK2 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 53/102 reads (52%) | catalogued as rs772744665, COSV67570332, COSV67685252; called by muse, mutect2, varscan2
- JMJD1C | c.5889T>G p.S1963R | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as COSV100550873; called by muse, mutect2, varscan2
- JRKL | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1463807331; called by muse, mutect2, varscan2
- KANK4 | c.2879A>G p.D960G | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470436113; called by muse, mutect2, varscan2
- KANSL1 | c.3106C>T p.R1036W (on ENST00000574590 / NM_001193465.2; = p.R1037W on NM_015443.4) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1345049239; called by muse, mutect2, varscan2
- KANSL1 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52264616; called by muse, mutect2, varscan2
- KAT6B | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 214/518 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs766989154, COSV54741295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KAT6B | c.5006A>G p.D1669G | Missense Mutation (SNP) | VAF 130/294 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1174024162; called by muse, mutect2, varscan2
- KCNA10 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 83/190 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773174747, COSV63905362; called by muse, mutect2, varscan2
- KCNC2 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 202/482 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100128745; called by muse, mutect2, varscan2
- KCNH1 | c.1558C>T p.R520W (on ENST00000271751 / NM_172362.3; = p.R493W on NM_002238.4) | Missense Mutation (SNP) | VAF 113/268 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55076714; called by muse, mutect2, varscan2
- KCNH6 | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs574008965; called by muse, mutect2, varscan2
- KCNH8 | c.1982T>C p.F661S | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60467859; called by muse, mutect2, varscan2
- KCNJ3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 108/239 reads (45%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs201650481, COSV54544929, COSV99716544; called by muse, varscan2
- KCNMA1 | c.2489G>A p.R830Q (on ENST00000286628 / NM_001161352.2; = p.R772Q on NM_002247.4) | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs771807869; called by muse, mutect2, varscan2
- KCTD14 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374366969; called by muse, mutect2, varscan2
- KDM4B | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs1422788948; called by muse, mutect2, varscan2
- KDM6B | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 336/768 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV54679549; called by muse, mutect2, varscan2
- KHDRBS2 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV55492706; called by muse, mutect2, varscan2
- KIAA0232 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 92/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749736948, COSV56925015; called by muse, mutect2
- KIAA0408 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs186474406; called by muse, mutect2, varscan2
- KIAA0586 | c.2986G>A p.E996K (on ENST00000619416 / NM_001244190.2; = p.E935K on NM_014749.5) | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs755889131; called by muse, mutect2, varscan2
- KIAA1549L | c.2039C>T p.S680L (on ENST00000321505; = p.S977L on NM_012194.3) | Missense Mutation (SNP) | VAF 102/205 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs776598262, COSV55771999; called by muse, mutect2, varscan2
- KIAA2012 | c.3289C>T p.R1097W | Missense Mutation (SNP) | VAF 131/294 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as rs778992896; called by muse, mutect2, varscan2
- KIAA2026 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs754732111, COSV67354492; called by muse, mutect2, varscan2
- KIF1A | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV57486010; called by muse, mutect2, varscan2
- KIF22 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs139450040; called by muse, mutect2, varscan2
- KIF23 | c.2416C>T p.R806C (on ENST00000260363; = p.R702C on NM_004856.7) | Missense Mutation (SNP) | VAF 94/193 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV52983357; called by muse, mutect2, varscan2
- KIF4A | c.2787G>T p.E929D | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as COSV65546173; called by muse, varscan2
- KIF5A | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 161/398 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161615188, COSV54051576, COSV54056394; called by muse, mutect2, varscan2
- KIF5C | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs764718591, COSV68479597; called by muse, mutect2, varscan2
- KIR2DL4 | c.952C>T p.P318S (on ENST00000396284; = p.P244S on NM_001080770.2) | Missense Mutation (SNP) | VAF 111/259 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs771853540, COSV58493509; called by muse, mutect2, varscan2
- KLB | c.334C>A p.H112N | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as rs370172876; called by muse, mutect2, varscan2
- KLF3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as rs377705302; called by muse, mutect2, varscan2
- KLHL25 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.45); catalogued as COSV61996461; called by muse, mutect2
- KLHL28 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.317); catalogued as rs779407331, COSV61887831; called by muse, mutect2, varscan2
- KLHL31 | c.1099C>A p.L367I | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV104426649, COSV63881866; called by muse, mutect2, varscan2
- KLHL8 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 68/155 reads (44%) | catalogued as COSV56747353; called by muse, mutect2, varscan2
- KMT2C | c.10615C>A p.L3539I | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs760204735; called by muse, mutect2, varscan2
- KMT2C | c.5881G>T p.D1961Y | Missense Mutation (SNP) | VAF 102/265 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100072830; called by muse, mutect2, varscan2
- KPNA7 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 152/322 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs754676038, COSV59398498; called by muse, mutect2, varscan2
- KPRP | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 93/180 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175728082, COSV64221236; called by muse, mutect2, varscan2
- KRT2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 182/366 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs770617369; called by muse, mutect2, varscan2
- KRT20 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as rs201355464, COSV99391348; called by muse, mutect2, varscan2
- KRT26 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.088); catalogued as COSV59415608; called by muse, mutect2, varscan2
- KRT38 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 217/462 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs571501521, COSV55845161; called by muse, mutect2, varscan2
- KRT39 | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs200782041, COSV62916868; called by muse, mutect2, varscan2
- KRTAP1-5 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 164/374 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs763635348, COSV100721336, COSV62624070; called by muse, varscan2
- LAMA2 | c.5932C>A p.L1978I | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs368316367, COSV70351327; called by muse, mutect2, varscan2
- LAMA3 | c.6976G>A p.E2326K (on ENST00000313654 / NM_198129.4; = p.E717K on NM_000227.6) | Missense Mutation (SNP) | VAF 181/424 reads (43%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.924); catalogued as rs148831718; called by muse, mutect2, varscan2
- LAMA5 | c.9400C>T p.R3134C | Missense Mutation (SNP) | VAF 132/270 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs527675374, COSV53364931; called by muse, varscan2
- LAMB3 | c.2915G>A p.R972Q | Missense Mutation (SNP) | VAF 138/340 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs143547447; called by muse, mutect2, varscan2
- LARP6 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 157/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54581589; called by muse, mutect2, varscan2
- LARP7 | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV60521539; called by muse, mutect2, varscan2
- LATS2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 92/173 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV66876540; called by muse, mutect2, varscan2
- LDB3 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 182/446 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as rs201689564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LEMD3 | c.1610G>A p.R537Q | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); catalogued as rs761447049, COSV100384517; called by muse, mutect2, varscan2
- LHCGR | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 134/303 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54295203; called by muse, mutect2, varscan2
- LIFR | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 112/264 reads (42%) | catalogued as rs1211214032; called by muse, mutect2, varscan2
- LIMK2 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 72/177 reads (41%) | catalogued as rs114127458, COSV59181311; called by muse, mutect2, varscan2
- LIN7A | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54021621; called by muse, mutect2, varscan2
- LIPH | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV56184926; called by muse, mutect2, varscan2
- LMLN | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs1447175554, COSV57597484; called by muse, mutect2, varscan2
- LMNTD1 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104391737; called by muse, mutect2, varscan2
- LONRF3 | c.1702G>A p.V568I (on ENST00000371628 / NM_001031855.3; = p.V527I on NM_024778.5) | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.747); catalogued as rs1428085666, COSV100504375; called by muse, mutect2, varscan2
- LPCAT2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs779380424, COSV50896983; called by muse, mutect2, varscan2
- LRP1B | c.7324C>A p.L2442I | Missense Mutation (SNP) | VAF 86/207 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs760574648, COSV101256207, COSV67217023; called by muse, mutect2, varscan2
- LRP2 | c.9235G>A p.E3079K | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as rs150220973; called by muse, mutect2, varscan2
- LRP6 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 189/450 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53796459; called by muse, mutect2, varscan2
- LRRC37A3 | c.3604G>A p.E1202K | Missense Mutation (SNP) | VAF 286/646 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs140182770, COSV100141027; called by mutect2, varscan2
- LRRC43 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 137/304 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs563015932, COSV60291486; called by muse, mutect2, varscan2
- LRRC7 | c.1813C>T p.R605* (on ENST00000651989 / NM_001370785.2; = p.R572* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 68/153 reads (44%) | catalogued as COSV50485026; called by muse, mutect2, varscan2
- LRRC7 | c.2504C>T p.S835L (on ENST00000651989 / NM_001370785.2; = p.S802L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs372385321, COSV50416022; called by muse, mutect2, varscan2
- LTF | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754476078, COSV51607516; called by muse, mutect2, varscan2
- LTV1 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs924212185, COSV100849568; called by muse, mutect2, varscan2
- LUM | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV57127889, COSV57128713; called by muse, mutect2, varscan2
- MACF1 | c.3209G>A p.R1070Q | Missense Mutation (SNP) | VAF 68/189 reads (36%) | catalogued as rs775574647; called by muse, mutect2, varscan2
- MACO1 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV65476383; called by muse, mutect2, varscan2
- MAG | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs751214414, COSV62699586; called by muse, mutect2
- MAGEA1 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 70/181 reads (39%) | catalogued as rs781993726, COSV63118763; called by muse, mutect2, varscan2
- MAGEA11 | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60754166, COSV60754525; called by muse, mutect2, varscan2
- MAGEB16 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 91/106 reads (86%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as rs200508397, COSV101303303; called by muse, mutect2, varscan2
- MAGEB6B | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs780519025, COSV69689925; called by muse, mutect2, varscan2
- MAGEH1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.187); catalogued as rs1171585695; called by muse, mutect2, varscan2
- MAGI3 | c.2318T>G p.L773R | Missense Mutation (SNP) | VAF 150/356 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56828740; called by muse, mutect2, varscan2
- MAGI3 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56829478, COSV56840127; called by muse, mutect2, varscan2
- MAP1B | c.4516G>T p.D1506Y | Missense Mutation (SNP) | VAF 82/169 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57095881; called by muse, mutect2, varscan2
- MAP3K4 | c.4210C>T p.R1404W | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1029881566, COSV62331302; called by muse, mutect2, varscan2
- MAP3K7 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100997940; called by muse, varscan2
- MAP4K2 | c.2377G>T p.D793Y | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as COSV99580692; called by muse, mutect2, varscan2
- MAP7 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs914123425, COSV63418630, COSV63420299; called by muse, mutect2, varscan2
- MAP7D3 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.079); catalogued as rs372609944, COSV100286084; called by muse, mutect2, varscan2
- MARCHF6 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs189021041, COSV56880169; called by muse, mutect2, varscan2
- MARCHF6 | c.1775G>A p.R592Q | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV56879223; called by muse, mutect2, varscan2
- MATN4 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 66/146 reads (45%) | PolyPhen probably damaging (0.999); catalogued as rs769518371, COSV59213449; called by muse, mutect2, varscan2
- MCF2 | c.2078A>G p.K693R | Missense Mutation (SNP) | VAF 129/273 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as COSV58498412; called by muse, mutect2, varscan2
- MCM9 | c.2981C>T p.S994L | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as rs1351910743; called by muse, mutect2, varscan2
- MCPH1 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 111/478 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs188726432, COSV60916961; called by muse, mutect2, varscan2
- MDC1 | c.3646G>A p.D1216N | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as rs778637501; called by muse, varscan2
- MDH1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1370337849; called by muse, mutect2, varscan2
- MDM1 | c.2124G>T p.E708D | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV100291572; called by muse, mutect2, varscan2
- MDN1 | c.9338C>T p.S3113L | Missense Mutation (SNP) | VAF 131/291 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs756074546, COSV65524504; called by muse, mutect2, varscan2
- MDN1 | c.4546C>T p.R1516C | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1234920779, COSV65519350, COSV65521119; called by muse, varscan2
- MED12L | c.3895G>T p.E1299* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as COSV56386358; called by muse, mutect2, varscan2
- MEGF11 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs761782026, COSV56552262; called by muse, mutect2, varscan2
- MET | c.4141A>G p.T1381A | Missense Mutation (SNP) | VAF 154/375 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1292389793, COSV59272163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFN2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 188/459 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV52420297; called by muse, mutect2, varscan2
- MGA | c.2677C>T p.P893S | Missense Mutation (SNP) | VAF 106/283 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400075534; called by muse, mutect2, varscan2
- MGA | c.7474C>T p.R2492W (on ENST00000219905 / NM_001164273.1; = p.R2283W on NM_001080541.2) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1411818407, COSV54963139; called by muse, varscan2
- MGAM2 | c.3880G>A p.V1294M | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577938509; called by muse, mutect2, varscan2
- MGAT4C | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59830235; called by muse, mutect2, varscan2
- MICU1 | c.892G>A p.E298K (on ENST00000361114 / NM_001195518.2; = p.E304K on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as rs368702991; called by muse, mutect2, varscan2
- MIGA1 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 15/132 reads (11%) | catalogued as rs747991246; called by muse, mutect2, varscan2
- MLKL | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs577105895, COSV100087215; called by muse, mutect2, varscan2
- MMP19 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs764541674, COSV59451381; called by muse, mutect2, varscan2
- MMS19 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 125/284 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs149505831; called by muse, mutect2, varscan2
- MMS22L | c.1245C>A p.F415L | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.156); catalogued as rs771911451; called by muse, mutect2, varscan2
- MNDA | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs774562125, COSV63740125; called by muse, mutect2, varscan2
- MOGS | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs200056332; called by muse, mutect2, varscan2
- MOXD1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs377603332; called by muse, mutect2, varscan2
- MROH7 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.535); catalogued as rs775977299, COSV59877391; called by muse, mutect2, varscan2
- MROH7 | c.3778G>A p.A1260T | Missense Mutation (SNP) | VAF 101/189 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs750024173, COSV64887166; called by muse, mutect2, varscan2
- MRPS10 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1203374761, COSV50002397; called by muse, varscan2
- MS4A4E | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 25/54 reads (46%) | catalogued as rs1333451911; called by muse, mutect2, varscan2
- MSH3 | c.534G>T p.K178N | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.617); catalogued as rs569679162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MST1R | c.3910C>T p.R1304W | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528985327, COSV56565008; called by muse, mutect2, varscan2
- MSX1 | c.653T>G p.I218R | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66946967; called by muse, mutect2, varscan2
- MTM1 | c.1237A>C p.S413R | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM151676; called by muse, mutect2, varscan2
- MTMR2 | c.1375C>T p.R459* | Nonsense Mutation (SNP) | VAF 120/303 reads (40%) | catalogued as rs1283810204, COSV60582004; called by muse, varscan2
- MTPAP | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV53933893; called by muse, mutect2
- MUC15 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.675); catalogued as COSV55555810, COSV55556013; called by muse, mutect2, varscan2
- MUC16 | c.15346G>A p.E5116K | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.041); catalogued as rs866107833, COSV67449897; called by muse, mutect2, varscan2
- MUC16 | c.13531T>G p.L4511V | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as COSV67494494; called by muse, mutect2, varscan2
- MUC17 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.129); catalogued as COSV60287093; called by muse, mutect2, varscan2
- MUC17 | c.5512C>T p.P1838S | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100072612; called by muse, mutect2, varscan2
- MUC2 | c.4141G>A p.D1381N | Missense Mutation (SNP) | VAF 127/344 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs758468511; called by muse, mutect2, varscan2
- MXD1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 55/144 reads (38%) | catalogued as rs761531529; called by muse, mutect2, varscan2
- MYBL1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV72918686; called by muse, mutect2, varscan2
- MYCBP2 | c.3893G>A p.R1298Q (on ENST00000357337; = p.R1336Q on NM_015057.5) | Missense Mutation (SNP) | VAF 99/120 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs776842585; called by muse, mutect2, varscan2
- MYH8 | c.5254C>T p.R1752C | Missense Mutation (SNP) | VAF 171/381 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs779138246; called by muse, mutect2, varscan2
- MYLK4 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759016773, COSV51139935; called by muse, varscan2
- MYMK | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs746683157, COSV60600038; called by muse, mutect2, varscan2
- MYO1D | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772153912, COSV59010156; called by muse, mutect2, varscan2
- MYO3A | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 127/289 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV56322804; called by muse, varscan2
- MYO5A | c.3043C>T p.R1015* | Nonsense Mutation (SNP) | VAF 124/300 reads (41%) | catalogued as COSV62560681; called by muse, varscan2
- MYO6 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 124/318 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64117379; called by muse, mutect2, varscan2
- MYOCD | c.2752G>A p.D918N | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748342025, COSV58509104; called by muse, mutect2, varscan2
- MYOF | c.4291G>A p.E1431K | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs775970286, COSV63702716; called by muse, mutect2, varscan2
- NAA35 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64485404; called by muse, mutect2, varscan2
- NACA | c.384C>T p.I128= | Splice Region (SNP) | VAF 68/145 reads (47%) | catalogued as rs758653483, COSV63268882, COSV63272062; called by muse, mutect2, varscan2
- NACA2 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 185/404 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs758594535, COSV71713068; called by muse, mutect2, varscan2
- NAP1L2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 34/110 reads (31%) | catalogued as COSV65172271; called by muse, varscan2
- NAT8 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 83/176 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1404309716; called by muse, mutect2, varscan2
- NAV2 | c.2804G>A p.R935Q (on ENST00000396087 / NM_001244963.2; = p.R912Q on NM_145117.5) | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs144524855; called by muse, mutect2, varscan2
- NAV3 | c.3745C>T p.R1249* | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | catalogued as rs1461827869, COSV57070023; called by muse, mutect2, varscan2
- NBEAL1 | c.6176G>A p.R2059Q | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770739816, COSV101355542, COSV68915665; called by muse, mutect2, varscan2
- NCBP3 | c.1233T>G p.I411M | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs768720440; called by muse, varscan2
- NCKAP1 | c.3244G>T p.E1082* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as CM124519, COSV100720029, COSV100720330; called by muse, mutect2, varscan2
- NCKAP5 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 55/141 reads (39%) | catalogued as rs756124627; called by muse, mutect2, varscan2
- NCL | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as rs775008554, COSV59547810; called by muse, mutect2, varscan2
- NCOA3 | c.2786G>T p.R929I | Missense Mutation (SNP) | VAF 140/322 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.61); catalogued as COSV59070646; called by muse, mutect2, varscan2
- NDNF | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs1182488275, COSV65633228; called by muse, mutect2, varscan2
- NDUFA1 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV65097390; called by muse, mutect2, varscan2
- NDUFS2 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 136/336 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1335942567, COSV57155479; called by muse, mutect2, varscan2
- NELFE | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 130/301 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs541259584, COSV64813495; called by muse, mutect2, varscan2
- NEMF | c.2533G>T p.E845* | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | catalogued as COSV100027565; called by muse, mutect2, varscan2
- NEUROD2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs1189635037; called by muse, mutect2, varscan2
- NEUROD4 | c.566A>C p.K189T | Missense Mutation (SNP) | VAF 111/273 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.349); catalogued as COSV54472233; called by muse, mutect2, varscan2
- NF1 | c.4385G>A p.R1462Q (on ENST00000358273 / NM_001042492.3; = p.R1441Q on NM_000267.3) | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs370852681, COSV62225249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NHS | c.2647G>A p.A883T | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs766667653, COSV66275668; called by muse, mutect2, varscan2
2,552 further variants in this file (1,577 protein-altering or splice-affecting, 598 silent, 377 other) are not listed here.
